Surgical pathology report (de-identified scan), TCGA case TCGA-IE-A4EI, project TCGA-SARC (Sarcoma), tissue source site ABS - IUPUI, specimen TCGA-IE-A4EI-01A (Primary Tumor).

[page 1 of 2]
Operative Procedure:

Radical resection left thigh mass

Pre-Operative Diagnosis:

Left thigh sarcoma

Specimen Received:

Left thigh sarcoma

Final Pathologic Diagnosis:

Soft tissue, left thigh, excision:

Leiomyosarcoma (6.5 cm in greatest dimension).

See Synoptic Report and Note below.

Synoptic Report

Procedure: Radical resection

Tumor site: Left thigh

Tumor size: 6.5 cm (greatest dimension)

Macroscopic extent of tumor: Cannot be determined

Histologic type: Leiomyosarcoma

Mitotic rate: 12/10 high-power fields (HPF)

Necrosis: Not identified

Histologic grade: High grade

Margins: Margins negative for sarcoma (Distance of sarcoma from

closest margin: 0.1 cm)

Specify margin: peripheral margin

Pathologic staging (pTNM)

TNM descriptors: None known

Primary tumor (pT): pT2b

Regional lymph nodes (pN): pNx cannot be assessed

Number examined: 0

Specify: Not applicable

Number involved: Not applicable

Specify: Not applicable

Distant metastasis (pM): pMx cannot be assessed

Additional pathologic findings: None

Ancillary studies

Immunohistochemistry: Performed on prior biopsy

Cytogenetics: Not performed

Molecular Pathology: Not performed

Radiographic findings: Not available

ICD-O-3

leiomyosarcoma, NOS 8890/3

Site: thigh, NOS C49.2

hw
9/25/12

[page 2 of 2]
Preresection treatment: Unknown
Treatment effect: Not identified

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received in formalin, labeled "left thigh sarcoma" is a 10.0 x 9.0 x 7.5 cm tan, lobulated, irregular resection of fat and muscle with attached long suture designating distal and short suture designating proximal. The specimen is inked as follows: Proximal-yellow, distal-green, remaining peripheral margins-black, Sectioning reveals a 6.5 x 5.6 x 5.0 cm tan-white to red, lobulated, hemorrhagic well delineated mass, which comes to within 0.1 cm from the nearest peripheral margin, 1.0 cm from the distal margin and 1.7 cm from the proximal margin. The remaining cut surface is tan, lobulated fatty tissue admixed with tan, homogeneous muscle.

Representative sections are submitted as follows:

- 1 proximal margin taken perpendicular;
- 2 distal margin taken perpendicular;
- 3-6 mass to four peripheral margins;
- 7-8 random mass.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken:

Gender: F

Source: NCI Genomic Data Commons file 438f7267-015b-4825-9b5d-5065585465ac (TCGA-IE-A4EI.5C1DD35D-3FE6-4C02-9546-024FFC6FE316.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).